Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVR, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVR-01A (Primary Tumor).

DIAGNOSIS:

Liver, right, hemihepatectomy:

Hepatocellular carcinoma

- 1) Post-chemembolization status: absent
- 2) Size of tumor: 2.5x2.5x2.2cm
- 3) Gross type: nodular with perinodal extension
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and compact
- 6) Cell type: classic cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: present (2%)
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the porta vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 0.8cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1), (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, inactive
- b) Dysplasia: absent

Gallbladder, cholecystectomy:

Chronic cholecystitis, mild

ICD O-3
Carcinoma, hepatocellular NOS
Site Liver C22.0
817013
QW 4/23/14

Source: NCI Genomic Data Commons file ab51982f-140f-4053-a545-ee8d4f5712b3 (TCGA-DD-AAVR.9CD3E7C0-EC70-4204-A919-0C5A33D8B4D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).